Somatic mutation profile of tumor specimen TCGA-AA-A01X-01A (aliquot TCGA-AA-A01X-01A-21W-A096-10) from TCGA case TCGA-AA-A01X, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage III; Age at diagnosis: 80.2 years (29,281 days).
Specimen TCGA-AA-A01X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e31ed8d2-77b2-497a-9418-8e41789ef877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01X-11A (Solid Tissue Normal), aliquot TCGA-AA-A01X-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0e308df-f2a0-4b26-8a49-cfbc5fa41403

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 19, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 104/247 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4637G>A p.R1546H (on ENST00000272895 / NM_173076.3; = p.R1228H on NM_015657.3) | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274612827, COSV55956227, COSV55978034; called by muse, mutect2, varscan2
- ADAMTS1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs910397647, COSV99536579; called by muse, mutect2
- ADAR | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 42/345 reads (12%) | catalogued as COSV99426842; called by muse, mutect2, varscan2
- AOC2 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 101/237 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs764975824, COSV53200408; called by muse, mutect2, varscan2
- APC | c.646-1G>T p.X216_splice | Splice Site (SNP) | VAF 42/228 reads (18%) | catalogued as rs78847145, CS971608, COSV57347627, COSV99970657; ClinVar: other; called by muse, mutect2, varscan2
- ARHGAP11A | c.937G>C p.A313P | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV100853379; called by muse, mutect2, varscan2
- BCL11A | c.2246G>A p.S749N (on ENST00000335712 / NM_001365609.1; = p.S783N on NM_022893.4) | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs61742690, COSV100186658, COSV59627016; called by muse, mutect2
- BOC | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.267); catalogued as COSV99849486; called by muse, mutect2, varscan2
- C10orf71 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368058122, COSV100110672; called by muse, mutect2, varscan2
- CDH17 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 182/802 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769967333, COSV99218146; called by muse, mutect2, varscan2
- COL2A1 | c.1631C>G p.A544G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.21); catalogued as COSV100477693; called by muse, mutect2
- COPB1 | c.2051G>A p.C684Y | Missense Mutation (SNP) | VAF 98/488 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs373743844, COSV99999972; called by muse, varscan2
- DLGAP2 | c.1555G>A p.V519I | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs371441823; called by muse, mutect2, varscan2
- FAT4 | c.9980G>A p.R3327H | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1319894221, COSV58697257; called by muse, mutect2, varscan2
- FGF11 | c.343A>T p.T115S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.05); catalogued as COSV99548555; called by muse, mutect2, varscan2
- FOXI1 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs750087966, COSV60388161; called by muse, mutect2, varscan2
- GALNT17 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144185040, COSV61149975, COSV61198066; called by muse, mutect2, varscan2
- GRIP1 | c.137-1G>C p.X46_splice | Splice Site (SNP) | VAF 19/125 reads (15%) | catalogued as COSV54015525, COSV99671246; called by muse, mutect2, varscan2
- IGLV3-9 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as rs780689649; called by muse, mutect2, varscan2
- ITGA7 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV57701917; called by muse, mutect2
- ITSN1 | c.4453G>A p.D1485N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67157696; called by muse, mutect2, varscan2
- KASH5 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs757572871, COSV71358558; called by muse, mutect2, varscan2
- KCNA3 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63901969; called by muse, mutect2, varscan2
- KCNH5 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1473460950, COSV100528377; called by muse, mutect2, varscan2
- L2HGDH | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748747271, COSV55561030; called by muse, mutect2, varscan2
- LMX1B | c.1153G>A p.V385M (on ENST00000373474 / NM_001174147.2; = p.V378M on NM_002316.4) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs750526845, COSV62739597; called by muse, mutect2, varscan2
- MMP7 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369414554; called by muse, mutect2, varscan2
- MPDZ | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 165/829 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100065071; called by muse, mutect2, varscan2
- MYT1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs761816010, COSV60511057; called by muse, mutect2
- NBEAL1 | c.6573G>A p.W2191* | Nonsense Mutation (SNP) | VAF 30/352 reads (9%) | catalogued as rs756672872, COSV101355635; called by muse, mutect2
- NSD3 | c.194A>G p.D65G | Missense Mutation (SNP) | VAF 98/1382 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as COSV100388988; called by muse, mutect2
- OR2G2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 146/1017 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV60740194, COSV60740632; called by muse, mutect2, varscan2
- OR56A4 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV58111953; called by muse, mutect2, varscan2
- OR6K3 | c.463C>T p.R155W (on ENST00000368146; = p.R139W on NM_001005327.2) | Missense Mutation (SNP) | VAF 289/426 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs550637792, COSV63745721, COSV63746101; called by muse, mutect2, varscan2
- PHLDB1 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782158725, COSV61876845; called by muse, mutect2, varscan2
- PPP6R3 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 70/331 reads (21%) | catalogued as COSV99677705; called by muse, mutect2, varscan2
- PSG8 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 115/363 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs200167716, COSV100126217; called by muse, mutect2, varscan2
- PTGIS | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs200895888, COSV99721350; called by muse, mutect2, varscan2
- PTH2R | c.1268A>G p.E423G | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99782977; called by muse, mutect2, varscan2
- SDCCAG8 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 51/1408 reads (4%) | catalogued as COSV100654700; called by muse, mutect2
- SLC13A3 | c.1793C>T p.T598I | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV99287381; called by muse, mutect2, varscan2
- SNTG1 | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1011585652, COSV52429815, COSV52433113; called by muse, mutect2, varscan2
- TDRD10 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 524/828 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779845457, COSV63813910; called by muse, varscan2
- TECTA | c.5672C>T p.T1891M | Missense Mutation (SNP) | VAF 389/847 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as rs200977539; called by muse, mutect2, varscan2
- TEFM | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1443050919, COSV60092786; called by muse, mutect2, varscan2
- TEX15 | c.1351G>A p.G451S (on ENST00000256246; = p.G834S on NM_001350162.2) | Missense Mutation (SNP) | VAF 71/354 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as COSV99822266; called by muse, mutect2, varscan2
- TLE4 | c.1477G>T p.V493L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV54642295, COSV99513399; called by muse, mutect2, varscan2
- TRAPPC10 | c.1813G>T p.V605F | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV52382004; called by muse, mutect2, varscan2
- UBN2 | c.801+2T>G p.X267_splice | Splice Site (SNP) | VAF 148/374 reads (40%) | catalogued as COSV99944552; called by muse, mutect2, varscan2
- UNK | c.135C>A p.C45* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99505647; called by muse, mutect2, varscan2
- ZNF14 | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV100694160; called by muse, mutect2, varscan2
- ANKIB1 | c.1632_1633del p.F544Lfs*6 | Frame Shift Del (DEL) | VAF 418/1486 reads (28%) | called by mutect2, pindel, varscan2
- APC | c.2873_2874del p.R958Ifs*4 | Frame Shift Del (DEL) | VAF 112/324 reads (35%) | called by pindel, varscan2
- OR2T29 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VPS18 | c.2902_2904del p.E968del | In Frame Del (DEL) | VAF 8/32 reads (25%) | called by pindel, varscan2
- CCR1 | c.897G>T p.V299= | Silent (SNP) | VAF 111/257 reads (43%) | catalogued as COSV99946824; called by muse, mutect2, varscan2
- COL6A3 | c.6147C>T p.I2049= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs536959688, COSV55085636; called by muse, mutect2, varscan2
- COQ8A | c.1557C>T p.T519= | Silent (SNP) | VAF 74/106 reads (70%) | catalogued as rs781346278, COSV62023262; called by muse, mutect2, varscan2
- CSMD1 | c.4011C>T p.D1337= (on ENST00000520002; = p.D1336= on NM_033225.6) | Silent (SNP) | VAF 218/471 reads (46%) | catalogued as rs779152958, COSV59391227; called by muse, mutect2, varscan2
- DST | c.2979T>C p.N993= (on ENST00000361203 / NM_001374722.1; = p.N667= on NM_001723.6) | Silent (SNP) | VAF 167/293 reads (57%) | catalogued as COSV55043003; called by muse, mutect2, varscan2
- ELP4 | c.330G>A p.G110= | Silent (SNP) | VAF 181/851 reads (21%) | catalogued as rs1241369434, COSV63358902; called by muse, mutect2, varscan2
- GIPC2 | c.690A>G p.K230= | Silent (SNP) | VAF 118/388 reads (30%) | catalogued as COSV66129670; called by muse, varscan2
- GJA8 | c.264G>A p.P88= | Silent (SNP) | VAF 164/231 reads (71%) | catalogued as rs1227166611, COSV53788592; called by muse, mutect2, varscan2
- HRNR | c.6576G>A p.S2192= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs567290240, COSV64260199, COSV64260339; called by muse, varscan2
- KCNS3 | c.549C>T p.S183= | Silent (SNP) | VAF 97/273 reads (36%) | catalogued as rs201603883, COSV58405075; called by muse, mutect2, varscan2
- MOV10L1 | c.1254C>T p.D418= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs144338444; called by muse, mutect2, varscan2
- OTOGL | c.2430A>G p.Q810= (on ENST00000547103; = p.Q801= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 290/652 reads (44%) | catalogued as COSV72007610; called by muse, mutect2, varscan2
- PAK5 | c.531C>T p.H177= | Silent (SNP) | VAF 197/475 reads (41%) | catalogued as COSV62039038; called by muse, mutect2, varscan2
- PCDHAC1 | c.2400T>C p.N800= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as COSV99170089; called by muse, mutect2
- SEZ6L | c.576G>A p.A192= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs368342681, COSV99962566; called by muse, mutect2, varscan2
- SLC6A3 | c.1377G>A p.L459= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs144403965; called by muse, mutect2
- TGM6 | c.2016C>A p.I672= | Silent (SNP) | VAF 88/199 reads (44%) | catalogued as COSV52478957, COSV52484711; called by muse, mutect2, varscan2
- TRAJ29 | c.27C>A p.V9= | Silent (SNP) | VAF 89/309 reads (29%) | catalogued as rs1454931619; called by muse, mutect2, varscan2
- ZFAT | c.90C>T p.H30= | Silent (SNP) | VAF 198/475 reads (42%) | catalogued as rs768351805, COSV64738856; called by muse, mutect2, varscan2
- C8orf31 | n.716C>A | RNA (SNP) | VAF 111/246 reads (45%) | called by muse, mutect2, varscan2
